Surgical pathology report (de-identified scan), TCGA case TCGA-53-7626, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site University of Miami, specimen TCGA-53-7626-01A (Primary Tumor).

[page 1 of 6]
RUN DATE:

PAGE 1

RUN TIME:

RUN USER:

FOR INTERNAL USE ONLY. NOT PART OF THE MEDICAL RECORD.

[REDACTED]

[REDACTED]

CODES: T26000 - BRONCHUS

T28000|M80001 - LUNG|NEOPLASM, UNCLER

T28000|M80003 - LUNG|NEOPLASM, MALIG

T29000|M80001 - PLEURA|NEOPLASM, UNCLER

T29030|M80001 - VISCERAL PLEURA|NEOPLASM, UNCLER

T29030|P200130 - VISCERAL PLEURA|CONSULTATION, N

TC4000 - LYMPH NODE

TC4000|M54000 - LYMPH NODE|NECROSIS, NOS

TC4000|M55400 - LYMPH NODE|CALCIUM DEPOSIT

TC4000|M78000 - LYMPH NODE|FIBROSIS, NOS

TC4000|M80106 - LYMPH NODE|CARCINOMA, META

TC4310 - PULMONARY LYMPH

Continued on next page ...

[page 2 of 6]
RUN DATE: [REDACTED]
RUN TIME: [REDACTED]
RUN USER: [REDACTED]

PAGE 2

FOR INTERNAL USE ONLY. NOT PART OF THE MEDICAL RECORD.

TC6020 - LYMPH, NOS

Undefined Provider

PROCEDURES: [REDACTED]

Edited by: [REDACTED]

TISSUES:

- A. . - RIGHT UPPER LOBE NODULE
- B. . - RIGHT UPPER LOBE LUNG
- C. . - RIGHT TRACHEOBRONCHIAL ANGLE, LYMPH NODE
- D. . - SUBCARINAL LYMPH NODE
- E. . - RIGHT DISTAL PERITRACHEAL LYMPH NODE
- F. . - INFERIOR PULMONARY LYMPH NODE

Edited by: [REDACTED]

ADDENDUM-

Addendum #1

THIS CASE WAS SEEN BY [REDACTED]

A. RIGHT UPPER LOBE NODULE:

- MODERATELY DIFFERENTIATED ADENOCARCINOMA.
- IT IS 1.2 CM.
- THE OVERLYING PLEURA IS FREE OF TUMOR.
- VASCULAR INVASION PRESENT.
- MARGIN FREE OF TUMOR.
- pT1 N1 MX.

B. RIGHT UPPER LOBE LUNG:

- SUBPLEURAL FIBROSIS.
- ONE (1) LYMPH NODE WITH NO MALIGNANCY SEE.
- BRONCHIAL MARGIN IS FREE OF TUMOR.
- NO TUMOR PRESENT.

C. RIGHT TRACHEOBRONCHIAL ANGLE, LYMPH NODE:

Continued on next page ...

[page 3 of 6]
RUN DATE
RUN TIME
RUN USER

PAGE 3

FOR INTERNAL USE ONLY. NOT PART OF THE MEDICAL RECORD.

ADDENDUM-

(Continued)

- METASTATIC ADENOCARCINOMA TO ONE (1) LYMPH NODE.

D. SUBCARINAL LYMPH NODE:

- LYMPH NODE WITH NECROTIZING GRANULOMATOUS HYALINIZATION.
- STAINS FOR ORGANISMS PENDING.
- NO MALIGNANCY SEEN.

E. RIGHT DISTAL PERITRACHEAL LYMPH NODE:

- ONE (1) LYMPH NODE WITH NO MALIGNANCY SEEN.

F. INFERIOR PUMONARY LYMPH NODE:

- ONE (1) LYMPH NODE WITH NO MALIGNANCY SEEN.

ADDENDUM

Addendum #1

SPECIAL STAINS FOR ABF AND FUNGI ARE NEGATIVE

CLINICAL HISTORY-

PRE-OP DX: PULMONARY LESION RIGHT UPPER LOBE

PROCEDURE: BRONCHOSCOPY, VIDEO THORACOSCOPY RIGHT THORACTOMY, RIGHT UPER LOBE LOBECTOMY

Edited by:

GROSS DESCRIPTION

SPECIMEN A IS LABELED RIGHT UPPER LOBE NODULE AND CONSISTS OF A 4 CM WEDGE RESECTION OF LUNG ON TRANSECTION IS 1-2 MM UNDER THE PUCKERED PLEURA IS A 1.0 TO 1.1 CM TAN GRAY NODULE WELL CIRCUMSCRIBED FROM THE SURROUNDING LUNG TISSUE. HALF IS SUBMITTED TO TISSUE BANK. THE REMAINDER IS SUBMITTED FOR FROZEN SECTION.

SPECIMEN B IS LABELED RIGHT UPPER LOBE LUNG RECEIVED IN FORMALIN AND CONSISTS OF RIGHT UPPER LOBE IS PURPLE TRIANGULAR SHAPED SEGMENT OF LUNG AND PLEURA WITH TWO STAPLES LINE UNDER MARGIN, MEASURING 14 X 11 X 2 CM AND WEIGHING 210 GRAMS. THE BRONCHIAL MARGIN IS

Continued on next page ...

[page 4 of 6]
RUN DATE: [REDACTED]
RUN TIME: [REDACTED]
RUN USER: [REDACTED]

PAGE 4

FOR INTERNAL USE ONLY. NOT PART OF THE MEDICAL RECORD.

GROSS DESCRIPTION

(Continued)

TAKEN FOR FROZEN SECTION. THE PLEURA IS ENGROSSED MEASURING 3 X 1.5 CM. MULTIPLE CROSS SECTION REVEALS RED-BROWN PARENCHYMA, ENPHIZEMATOUS CHANGES. ALSO REVEALS GRAY LIGHT-BROWN INDURATED AREA, MEASURING 3 X 1.5 CM. THIS AREA IS CONTINUITY FROM THE PLEURA. NO TUMOR IS SEEN GROSSLY. THE BRONCHIAL AND VASCULAR TREE ARE GROSSLY UNREMARKABLE. REPRESENTATIVE SECTIONS ARE SUBMITTED IN EIGHT CASSETTES.

1-4. PLEURA ENGROSSED

5-8. REPRESENTATIVE SECTIONS

SPECIMEN C RECEIVED IN FORMALIN IS LABELED RIGHT TRACHEOBRONCHIAL ANGLE AND CONSISTS OF YELLOW-GRAY ADIPOSE TISSUE, MEASURING 1.5 X 1 X 0.3 CM AND REVEALS ONE DARK-BROWN TO BLACK NODULE, MEASURING 0.8 CM IN GREATEST DIMENSION. SECTIONS ARE SUBMITTED IN TOTO IN TWO CASSETTES.

SPECIMEN D RECEIVED IN FORMALIN IS LABELED SUBCARINAL LYMPH NODE AND CONSISTS OF THREE YELLOW-GRAY SOFT TISSUE FRAGMENTS, MEASURING IN AGGREGATE 2.5 X 1 X 0.4 CM. CUT SECTIONS REVEAL TWO POSSIBLE LYMPH NODES, MEASURING UP TO 0.6 CM IN GREATEST DIMENSION. SUBMITTED IN TOTO IN TWO CASSETTES.

1. LYMPH NODE

2. THE REMAINDER OF THE SPECIMEN

SPECIMEN E RECEIVED IN FORMALIN IS LABELED RIGHT DISTAL PERITRACHEAL LYMPH NODE AND CONSISTS OF GRAY-TAN ADIPOSE TISSUE, MEASURING 1.5 X 0.7 X 0.2 CM. SUBMITTED IN TOTO IN ONE CASSETTE.

SPECIMEN F RECEIVED IN FORMALIN IS LABELED INFERIOR PULMONARY LYMPH NODE AND CONSISTS OF GRAY-TAN AND IRREGULARLY SHAPED SOFT TISSUE FRAGMENT, MEASURING 0.5 X 0.4 X 0.2 CM. SUBMITTED IN TOTO IN ONE CASSETTE.

Dictated by [REDACTED]
Edited by: [REDACTED]

***** FINAL DIAGNOSIS *****

A. NODULE/RIGHT UPPER LOBE LUNG

- ADENOCARCINOMA OF LUNG WITH BUTTING UPTO THE PLEURAL SURFACE NOT GOING THROUGH. MARGINS ARE FREE OF TUMOR.

B. RIGHT UPPER LOBE LUNG :

- BRONCHIAL MARGIN IS NEGATIVE FOR TUMOR

- ANTHRACOTIC PERIBRONCHIAL LYMPH NODE; NO TUMOR.

-LARGE FOCI OF PARENCHYMAL SCARRING WITH BRONCHIECTASIS, NO RESIDUAL TUMOR

Continued on next page ...

[page 5 of 6]
RUN DATE:
RUN TIME:
RUN USER:

PAGE 5

FOR INTERNAL USE ONLY. NOT PART OF THE MEDICAL RECORD.

*** FINAL DIAGNOSIS *** (Continued)

C. LYMPH NODE/RIGHT TRACHEOBRONCHIAL ANGLE
- METASTATIC CARCINOMA TO LYMPH NODE (1 OF 1)

D. SUBCARINAL LYMPH NODE:
- LYMPH NODE WITH FIBROTIC GRANULOMAS WITH CENTRAL NECROSIS AND CALCIFICATION, NO TUMOR.

E. RIGHT DISTAL PERITRACHEAL LYMPH NODE:
- ANTHRACOTIC LYMPH NODE; NO TUMOR.

F. INFERIOR PULMONARY LYMPH NODE:
- ANTHRACOTIC LYMPH NODE; NO TUMOR.

LUNG CANCER STAGING INFORMATION

SPECIMEN TYPE: LOBECTOMY

LATERALITY: RIGHT

TUMOR SITE: UPPER LOBE

TUMOR SIZE: GREATEST DIMENSION: 1.2

HISTOLOGIC TYPE: ADENOCARCINOMA, NOT OTHERWISE CHARACTERIZED

HISTOLOGIC GRADE: WELL DIFFERENTIATED, MODERATELY DIFFERENTIATED,

PRIMARY TUMOR (pT): pT1: TUMOR 3 CM OR LESS IN GREATEST DIMENSION, SURROUNDED BY LUNG OR VISCERAL PLEURA, WITHOUT BRONCHOSCOPIC EVIDENCE OF INVASION MORE PROXIMAL THAN THE LOBAR BRONCHUS (IE. NOT IN THE MAIN BRONCHUS)

REGIONAL LYMPH NODES:

NUMBER EXAMINED: 7

NUMBER INVOLVED: 1

DISTANT METASTASIS (pM): pMX: CANNOT BE ASSESSED

MARGINS: UNINVOLVED BY INVASIVE CARCINOMA DISTANCE FROM CLOSEST MARGIN: 1 mm.

CLOSEST MARGIN: VISCERAL PLEURA

DIRECT EXTENSION OF THE TUMOR: NONE IDENTIFIED

VENOUS (LARGE VESSEL) INVASION: ABSENT

ARTERIAL (LARGE VESSEL) INVASION: ABSENT

Continued on next page ...

[page 6 of 6]
RUN DATE:

RUN TIME:

RUN USER:

PAGE 6

FOR INTERNAL USE ONLY. NOT PART OF THE MEDICAL RECORD.

A. ADENOCARCINOMA OF LUNG WITH BUTTING UPTO THE PLEURAL SURFACE NOT GOING THROUGH. MARGINS ARE FREE OF TUMOR.

B. RIGHT UPPER LOBE LUNG - BRONCHIAL MARGIN IS NEGATIVE FOR TUMOR
- ANTHRACOTIC PERIBRONCHIAL LYMPH NODE; NO TUMOR.

*** End of Report ***

Source: NCI Genomic Data Commons file 8e1ee43e-6142-43ba-a650-bd4b08982047 (TCGA-53-7626.23A82F88-D450-4546-88E0-C26CF8DE267E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).